TCGA case TCGA-3B-A9HU — Sarcoma (TCGA-SARC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Myomatous Neoplasms; Primary site: Retroperitoneum and peritoneum; Tissue source site: Moffitt Cancer Center. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/9ef5cdda-8aba-4027-8cf0-e53b2f54704a

Demographics
Sex at birth: female; Race: black or african american; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 53 years; Vital status: Alive.

Diagnoses (3)
1. Leiomyosarcoma, NOS (the primary disease): ICD-O-3 morphology code: 8890/3; ICD-10 code: C48.0; Tissue or organ of origin: Retroperitoneum; Site of resection or biopsy: Retroperitoneum; Classification of tumor: primary; Age at diagnosis: 53.9 years (19,669 days); Year of diagnosis: 2010; Metastasis at diagnosis: Metastasis, NOS; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Residual disease: R0; Sites of involvement: Lung, NOS; Tumor focality: Unifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor depth measurement: 7.1; Tumor length measurement: 7.9; Tumor width measurement: 7.4.
   Pathology details: Consistent pathology review: Yes; Margin status: Uninvolved; Necrosis percent: 10; Necrosis present: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 8.9; Tumor width measurement: 9.
2. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Lung, NOS. Age at diagnosis: 55.6 years (20,300 days); Days to diagnosis: 631 days (1.7 years); Prior treatment: Yes; Tumor focality: Multifocal.
   Pathology details: Measurement type: Pathologic; Measurement unit: Centimeters; Tumor length measurement: 0.4.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 0.5.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.
3. Metastasis of diagnosis 1 (Leiomyosarcoma, NOS), site: Liver. Age at diagnosis: 55.9 years (20,415 days); Days to diagnosis: 746 days (2.0 years); Prior treatment: Yes.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.5.
   Pathology details: Measurement type: Radiologic; Measurement unit: Centimeters; Tumor length measurement: 1.5.
   Recorded as not given: Pharmaceutical Therapy, NOS, for progressive disease.

Follow-up (3 entries)
- Day 631 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Lung, NOS; Days to progression: 631 days (1.7 years); Discontiguous lesion count: 2.
- Day 746 (post initial treatment): Progression or recurrence: Yes; Progression or recurrence type: Distant; Progression or recurrence anatomic site: Liver; Days to progression: 746 days (2.0 years).
- Days to follow up: 768 days (2.1 years); Disease response: With Tumor.

Molecular and laboratory tests
- Test: Mitotic Count Reported; Mitotic count: 6.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-3B-A9HU-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 60 mg.
  Slide TCGA-3B-A9HU-01A-01-TS1: Section location: Top; Percent tumor cells: 100; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 0; Percent lymphocyte infiltration: 1; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
- Sample TCGA-3B-A9HU-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-3B-A9HU-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: With tumor.
- Primary pathology: Histologic diagnosis: Leiomyosarcoma (LMS); Histologic subtype: Conventional leiomyosarcoma; Leiomyo major vessel involvement: No Major Vessel Involvement; Margin status: Negative; Tumor total necrosis: Moderate Necrosis (>=10, <50%); Disease multifocal indicator: No; Locoregional recurrence indicator: No; Metastatic disease confirmed: Yes; Metastasis site: Lung; Contiguous organ invaded: No.
- Primary pathology, Tumor tissue sites: Submitted tumor site: Retroperitoneum/Upper abdominal - Retroperitoneum.
- Primary pathology, Tumor sizes, Tumor size: Lesion radiologic width: 9.
- Follow-up form: Lost to follow-up: Yes; Tumor status: With tumor.

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 768 days; disease-specific survival: no event (censored), 768 days; disease-free interval: event (new tumor event after initially disease-free), 631 days; progression-free interval: event (progression, recurrence, new primary tumor or death with tumor), 631 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-3B-A9HU-01A-11D-A38Y-01): tumor purity 0.63, ploidy 1.8, whole-genome doublings 0.
